Somatic mutation profile of tumor specimen MP2PRT-PARXDT-TMP1-A (aliquot MP2PRT-PARXDT-TMP1-A-1-0-D-A79Q-36) from MP2PRT case MP2PRT-PARXDT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,150 days).
Specimen MP2PRT-PARXDT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 783017bb-9c68-47aa-91b9-a2e814099dae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARXDT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARXDT-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88b0743d-0ab3-4d71-a3c0-2b968656a5b7

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD26 | c.3128G>A p.R1043H | Missense Mutation (SNP) | VAF 96/375 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs780361039, COSV65777007; called by muse, mutect2, varscan2
- FOXP4 | c.1319G>A p.R440Q (on ENST00000307972 / NM_001012426.1; = p.R427Q on NM_138457.3) | Missense Mutation (SNP) | VAF 75/584 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs576059149, COSV57220668; called by muse, mutect2, varscan2
- NECTIN3 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 35/458 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs752554749; called by muse, mutect2
- ZNF532 | c.1934C>T p.T645M | Missense Mutation (SNP) | VAF 64/571 reads (11%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.476); catalogued as rs1484271879; called by muse, mutect2, varscan2
- EPHX3 | c.164G>A p.C55Y | Missense Mutation (SNP) | VAF 140/665 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- IGKV2D-24 | chr2:90005628 CTCACACAGT>TCAATG | Missense Mutation (DEL) | VAF 25/103 reads (24%) | called by pindel, varscan2*
- PTGES3L-AARSD1 | c.277G>C p.E93Q (on ENST00000421990 / NM_001136042.2; = p.E75Q on NM_025267.3) | Missense Mutation (SNP) | VAF 22/406 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); called by muse, mutect2
- SPANXN3 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 56/251 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- UHRF1 | c.5_6insTTTT p.W2Cfs*67 (on ENST00000612630 / NM_001290050.1; = p.W15Cfs*67 on NM_013282.4) | Frame Shift Ins (INS) | VAF 90/324 reads (28%) | called by mutect2, pindel*, varscan2
- ASTN2 | c.189C>T p.C63= | Silent (SNP) | VAF 90/745 reads (12%) | catalogued as rs1435879953; called by muse, mutect2, varscan2
- IL10RA | c.942C>T p.H314= | Silent (SNP) | VAF 94/468 reads (20%) | catalogued as rs763364696; called by muse, mutect2, varscan2
- SRRT | c.1137T>C p.A379= | Silent (SNP) | VAF 34/322 reads (11%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | c.582+32799G>A | Intron (SNP) | VAF 80/570 reads (14%) | called by mutect2, varscan2
